Somatic mutation profile of tumor specimen TCGA-2H-A9GN-01A (aliquot TCGA-2H-A9GN-01A-11D-A37C-09) from TCGA case TCGA-2H-A9GN, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 70.3 years (25,664 days).
Specimen TCGA-2H-A9GN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 189e78eb-7b62-4d3e-94f2-7c73ec694621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GN-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GN-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3f76356-7090-4acd-a621-0316baf5abae

The open-access MAF lists 116 somatic variants for this specimen: 89 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 77, Silent 27, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs193922770, CM971325, COSV62102500; ClinVar: pathogenic / drug response; called by muse, mutect2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 34/45 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 30/50 reads (60%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACADL | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs758491059, COSV52052319; called by muse, mutect2, varscan2
- ADAMTS13 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs587701622, COSV63020852; called by muse, mutect2, varscan2
- AHNAK2 | c.12076G>C p.E4026Q | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.839); catalogued as rs747366338, COSV60915566; called by muse, mutect2, varscan2
- ANAPC2 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60571080, COSV60572735; called by muse, mutect2, varscan2
- APOC3 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs149707394, CM942307; called by muse, mutect2, varscan2
- ATN1 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs201715319, COSV100755715, COSV63113374; called by muse, mutect2, varscan2
- CCDC74A | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs376130814; called by muse, mutect2, varscan2
- COL9A1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV100294535; called by muse, mutect2, varscan2
- CTDSPL2 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs774125416, COSV52944804; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1511A>G p.Y504C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs762701312; called by muse, mutect2, varscan2
- GGN | c.182T>C p.M61T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1275866286; called by muse, mutect2, varscan2
- HLA-DPA1 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70088363; called by muse, mutect2, varscan2
- HTR3B | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as rs370926260; called by muse, mutect2, varscan2
- KHDRBS3 | c.199T>G p.F67V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV63421506; called by muse, mutect2, varscan2
- LRRC4B | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV65349610, COSV65350566; called by muse, mutect2, varscan2
- MUC5B | c.4910C>T p.P1637L | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs776605835, COSV71590622; called by muse, mutect2, varscan2
- MYH9 | c.4493T>G p.L1498R | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.52); PolyPhen benign (0.119); catalogued as COSV53392609; called by muse, mutect2, varscan2
- MYT1 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.735); catalogued as COSV60504285; called by muse, mutect2, varscan2
- NOTCH1 | c.5087C>T p.A1696V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.672); catalogued as COSV53034439; called by muse, mutect2, varscan2
- NUDT14 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.45); catalogued as rs767168556, COSV59307883; called by muse, mutect2, varscan2
- P2RY6 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs574690210, COSV62936426; called by muse, mutect2, varscan2
- PCDH15 | c.1040T>G p.L347R | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57299220, COSV57350026; called by muse, mutect2, varscan2
- PKLR | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs1456158956; called by muse, mutect2
- PPOX | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758609195, COSV57091768; called by muse, mutect2, varscan2
- PREX1 | c.426C>G p.F142L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100906583; called by muse, mutect2, varscan2
- PRPH2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs960152679, COSV100027926; called by muse, mutect2, varscan2
- PRTG | c.976C>G p.P326A | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV66840301; called by muse, mutect2, varscan2
- PTPN13 | c.6365G>A p.C2122Y (on ENST00000411767 / NM_080683.3; = p.C2103Y on NM_006264.3) | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs761040655; called by muse, mutect2, varscan2
- RP1 | c.3831T>G p.S1277R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1433561880; called by muse, mutect2, varscan2
- SEMA5B | c.2291C>T p.T764M | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as rs1277731715; called by muse, mutect2
- SF3B2 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.17); catalogued as rs886612846, COSV59427638; called by muse, mutect2, varscan2
- SIRPG | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs748098905; called by muse, mutect2, varscan2
- SLC17A6 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV54134197; called by muse, varscan2
- SLC28A3 | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs753913265, COSV66152424; called by muse, mutect2, varscan2
- SLC35F5 | c.1512C>G p.S504R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.308); catalogued as COSV99830026; called by muse, mutect2, varscan2
- SUN5 | c.656A>G p.H219R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as rs1183076306; called by muse, mutect2, varscan2
- TAS2R20 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs752429456; called by muse, varscan2
- TNFRSF18 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763921252, COSV60775094; called by muse, mutect2, varscan2
- VCX3A | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as rs1203324384; called by muse, mutect2, varscan2
- VPS50 | c.2061A>C p.E687D | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV100005426; called by muse, mutect2, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by pindel, varscan2
- ZC3H18 | c.936A>T p.L312F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV56322579; called by muse, mutect2
- ZNF835 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV101606392; called by muse, mutect2, varscan2
- ARSI | c.1553del p.G518Vfs*47 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- ATAT1 | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- BPIFA1 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C16orf89 | c.796T>G p.F266V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CARMIL1 | c.1033T>G p.S345A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CD96 | c.750_751del p.R250Sfs*4 (on ENST00000283285 / NM_198196.3; = p.R234Sfs*4 on NM_005816.5) | Frame Shift Del (DEL) | VAF 34/116 reads (29%) | called by pindel, varscan2
- CDK13 | c.1433A>C p.K478T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CLYBL | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.4); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DMXL1 | c.2722G>A p.V908I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNLT3 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT tolerated (0.12); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- GGT7 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJD2 | c.338T>C p.F113S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2
- GRAMD1C | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- GRM8 | c.1937T>A p.I646N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- HACD3 | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELB | c.1260_1266dup p.D423Hfs*6 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- INTS1 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IVL | c.539A>G p.E180G | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- KAT6B | c.1291A>C p.T431P | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- LAMB1 | c.4746-2A>C p.X1582_splice | Splice Site (SNP) | VAF 43/57 reads (75%) | called by muse, mutect2, varscan2
- LPCAT4 | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- LTBP1 | c.2244C>G p.H748Q (on ENST00000404816 / NM_206943.4; = p.H422Q on NM_000627.4) | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- METTL25 | c.1249T>A p.L417I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- NCOA1 | c.3824C>T p.S1275F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NELFCD | c.1792G>T p.V598L (on ENST00000602795; = p.V580L on NM_198976.4) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP12 | c.1997A>T p.Y666F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- NMNAT1 | c.221C>G p.T74S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- PCDH10 | c.1640A>T p.D547V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PFKFB1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 12/15 reads (80%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SALL1 | c.1452C>A p.N484K | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCAP | c.836A>T p.E279V | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SCN2A | c.5012T>C p.M1671T | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SCN3B | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SEL1L3 | c.2353_2355del p.K785del | In Frame Del (DEL) | VAF 22/32 reads (69%) | called by mutect2, pindel, varscan2
- SLC26A9 | c.1795C>G p.Q599E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- SMO | c.802T>C p.F268L | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SOX17 | c.821T>G p.L274R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TPTE | c.424C>A p.L142I (on ENST00000618007 / NM_199261.4; = p.L124I on NM_199259.4) | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); called by muse, mutect2
- TRAM1 | c.97_100dup p.F34Cfs*9 | Frame Shift Ins (INS) | VAF 38/115 reads (33%) | called by mutect2, pindel, varscan2
- TRPM5 | c.1169G>C p.S390T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ZMYM6 | c.3763C>G p.Q1255E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); called by muse, mutect2
- ZNF528 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- ZNF544 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- ADGRG4 | c.4956T>G p.T1652= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- AP5Z1 | c.864G>A p.P288= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs372643577; called by muse, mutect2, varscan2
- CAB39 | c.324A>G p.R108= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV51476489; called by muse, mutect2, varscan2
- CXCR2 | c.828C>A p.L276= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- DOK5 | c.348C>T p.I116= | Silent (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- DST | c.17974T>C p.L5992= (on ENST00000361203 / NM_001374722.1; = p.L3689= on NM_015548.5) | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- ESYT3 | c.1644C>T p.C548= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs1188555936; called by muse, mutect2, varscan2
- FREM2 | c.2559C>T p.H853= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs779617548, COSV99749716; ClinVar: likely benign; called by muse, mutect2, varscan2
- HAL | c.1059T>C p.H353= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- IL27RA | c.1284C>T p.A428= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- INHBB | c.1068C>T p.N356= | Silent (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- KRTAP11-1 | c.36C>T p.S12= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- KRTAP2-4 | c.348G>A p.P116= | Silent (SNP) | VAF 53/75 reads (71%) | called by muse, mutect2, varscan2
- LPCAT4 | c.765C>T p.L255= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs760136372; called by muse, mutect2, varscan2
- MUC5B | c.11727C>T p.V3909= | Silent (SNP) | VAF 84/225 reads (37%) | catalogued as rs1430121849; called by muse, mutect2, varscan2
- NANOS2 | c.351C>T p.N117= | Silent (SNP) | VAF 175/274 reads (64%) | catalogued as rs575299215, COSV58024739; called by muse, mutect2, varscan2
- NOA1 | c.1131C>A p.I377= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- NR1H2 | c.1248C>G p.R416= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs993701646; called by muse, mutect2, varscan2
- NUP188 | c.4729C>T p.L1577= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV65331814; called by muse, mutect2
- OTOF | c.1851G>A p.L617= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs558573899; called by muse, mutect2
- PIRT | c.291G>T p.L97= | Silent (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.418A>C p.R140= | Silent (SNP) | VAF 83/298 reads (28%) | called by muse, mutect2, varscan2
- RASSF2 | c.202C>T p.L68= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs777291217, COSV101040862; called by muse, mutect2, varscan2
- RPIA | c.228C>T p.S76= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as rs201068417; called by muse, mutect2, varscan2
- TCEA1 | c.261C>T p.D87= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs774732291; called by muse, mutect2, varscan2
- UBR4 | c.3381G>A p.A1127= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs374365470; called by muse, mutect2, varscan2
- XK | c.138G>A p.L46= | Silent (SNP) | VAF 43/49 reads (88%) | catalogued as rs1292349886; called by muse, mutect2, varscan2
